Somatic mutation profile of tumor specimen 0DB56F from CCDI case PBBKUH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.7 years (969 days).
Specimen 0DB56F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95dc2f94-c134-4e9f-9823-f25c0cf293e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB56G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ccf9b21-fda7-4a91-9da8-7e998583691b

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GSG1L2 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 12/369 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs978143766; called by muse, mutect2
- HIRA | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54271730; called by muse, mutect2, varscan2
- SREBF1 | c.3251G>A p.R1084Q | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1006601364; called by muse, mutect2, varscan2
- SLC12A9 | c.2029dup p.A677Gfs*33 | Frame Shift Ins (INS) | VAF 74/230 reads (32%) | called by mutect2, pindel, varscan2
